Somatic mutation profile of tumor specimen TCGA-P3-A6T2-01A (aliquot TCGA-P3-A6T2-01A-11D-A34J-08) from TCGA case TCGA-P3-A6T2, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cheek mucosa; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 45.4 years (16,588 days).
Specimen TCGA-P3-A6T2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) faf51d1a-72ea-4d81-842e-aba1f387284a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P3-A6T2-10A (Blood Derived Normal), aliquot TCGA-P3-A6T2-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78fea091-df92-40e0-befd-f4ec72736fb2

The open-access MAF lists 63 somatic variants for this specimen: 36 protein-altering or splice-affecting, 25 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 25, Nonsense Mutation 2, 3'UTR 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 40/70 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as rs104894230, CM053284, CM081305, CM123157, COSV54236734, COSV54236774, COSV54238174; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- HRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 45/73 reads (62%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.385); catalogued as rs104894229, CM053283, CM061797, COSV54236795, COSV54236828, COSV54237299; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.775G>A p.D259N | Missense Mutation (SNP) | VAF 21/55 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as COSV52662086, COSV52675732, COSV52773165, COSV52962390; called by muse, mutect2, varscan2
- ADAMTS19 | c.1586G>A p.R529Q | Missense Mutation (SNP) | VAF 39/198 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.009); catalogued as rs188910013, COSV50731320; called by muse, mutect2, varscan2
- ADH5 | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.324); catalogued as COSV99596203; called by muse, mutect2, varscan2
- AFF2 | c.1373C>A p.A458E | Missense Mutation (SNP) | VAF 71/101 reads (70%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as COSV99662834; called by muse, mutect2, varscan2
- ATRIP | c.2245G>A p.D749N (on ENST00000320211 / NM_130384.3; = p.D722N on NM_032166.4) | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56496707; called by muse, mutect2, varscan2
- CASP8 | c.1303C>T p.R435* (on ENST00000432109 / NM_033355.3; = p.R452* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 19/41 reads (46%) | catalogued as rs1368296717, COSV51844657; called by muse, mutect2, varscan2
- DYRK1A | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100117651; called by muse, mutect2, varscan2
- ERBIN | c.3055C>G p.Q1019E | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99396363; called by muse, mutect2, varscan2
- FRAS1 | c.1110G>T p.E370D | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV99349965; called by muse, mutect2, varscan2
- FRAS1 | c.6493G>A p.E2165K | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs762176301, COSV53650832, COSV99349973; called by muse, varscan2
- GRM3 | c.288G>C p.L96F | Missense Mutation (SNP) | VAF 82/224 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100862299; called by muse, mutect2, varscan2
- HSPG2 | c.152C>T p.S51L | Missense Mutation (SNP) | VAF 64/176 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs866719632, COSV101020529; called by muse, mutect2, varscan2
- LLCFC1 | c.300G>A p.M100I (on ENST00000458732; = p.M69I on NM_178829.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as COSV62333465; called by muse, mutect2, varscan2
- LRP1B | c.4137C>A p.H1379Q | Missense Mutation (SNP) | VAF 59/157 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101254548; called by muse, mutect2, varscan2
- LTB4R2 | c.841G>A p.A281T (on ENST00000528054; = p.A250T on NM_019839.5) | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.875); catalogued as COSV99350577; called by muse, mutect2, varscan2
- MAMDC2 | c.1266A>T p.L422F | Missense Mutation (SNP) | VAF 128/232 reads (55%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs151044274; called by muse, mutect2, varscan2
- MMP3 | c.509A>C p.D170A | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100242738; called by muse, mutect2, varscan2
- MYH9 | c.3740G>C p.R1247P | Missense Mutation (SNP) | VAF 53/153 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99338337; called by muse, mutect2, varscan2
- MYRIP | c.1555A>G p.T519A | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (0.81); PolyPhen benign (0.001); catalogued as COSV100218677; called by muse, mutect2, varscan2
- NEUROD6 | c.82C>A p.Q28K | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV99773954; called by muse, mutect2, varscan2
- OR8B3 | c.929G>C p.R310T | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV100660382, COSV63541234; called by muse, mutect2, varscan2
- OXSM | c.716G>T p.C239F | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99771955; called by muse, mutect2, varscan2
- PCDHAC1 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 63/194 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as rs1179807732, COSV53836554; called by muse, mutect2, varscan2
- PCED1B | c.1051G>T p.D351Y | Missense Mutation (SNP) | VAF 111/148 reads (75%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.888); catalogued as rs535665336, COSV101423624; called by muse, mutect2, varscan2
- PRG4 | c.1512G>T p.K504N | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as COSV100798147, COSV63355045; called by muse, mutect2, varscan2
- PTCHD4 | c.647C>G p.S216C | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.44); catalogued as COSV100260467; called by muse, mutect2, varscan2
- RPS6KA5 | c.1019G>T p.R340L | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.074); catalogued as COSV100002365; called by muse, varscan2
- RUNX1T1 | c.1255G>A p.V419I (on ENST00000265814 / NM_001198628.1; = p.V392I on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/179 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.048); catalogued as rs763084019, COSV56148701; called by muse, mutect2, varscan2
- SIRPG | c.343G>A p.G115S | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1201647688, COSV99403585; called by muse, mutect2, varscan2
- SLCO5A1 | c.2372G>A p.R791Q | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.083); catalogued as rs759957081, COSV52655549, COSV52662294; called by muse, mutect2, varscan2
- SMG1 | c.2185A>T p.K729* | Nonsense Mutation (SNP) | VAF 14/25 reads (56%) | catalogued as COSV101245493; called by muse, mutect2, varscan2
- SPATA31E1 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 110/195 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as COSV100350170; called by muse, mutect2, varscan2
- TP53 | c.848G>C p.R283P | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs371409680, CM021154, COSV52693421, COSV52700134, COSV52964971; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARID2 | c.3787del p.I1263Lfs*32 | Frame Shift Del (DEL) | VAF 46/80 reads (58%) | called by mutect2, pindel, varscan2
- ADAMTSL2 | c.1998C>T p.C666= | Silent (SNP) | VAF 18/28 reads (64%) | catalogued as rs1275994903; called by muse, mutect2, varscan2
- AHNAK2 | c.10083T>C p.P3361= | Silent (SNP) | VAF 164/379 reads (43%) | catalogued as rs1366192661, COSV100316569; called by muse, mutect2
- ARID2 | c.1278G>A p.T426= | Silent (SNP) | VAF 22/97 reads (23%) | catalogued as rs146341546; called by muse, mutect2, varscan2
- ATRX | c.6387T>C p.A2129= | Silent (SNP) | VAF 89/126 reads (71%) | catalogued as COSV100970350; called by muse, mutect2, varscan2
- CLCNKA | c.1500C>T p.P500= | Silent (SNP) | VAF 29/116 reads (25%) | catalogued as rs143389794; ClinVar: likely benign; called by muse, mutect2, varscan2
- CRTAC1 | c.318G>A p.A106= | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as rs765777184, COSV54001359; called by muse, mutect2, varscan2
- DAW1 | c.660C>T p.A220= | Silent (SNP) | VAF 51/143 reads (36%) | catalogued as rs1042819578, COSV59369522; called by muse, mutect2, varscan2
- DDX60 | c.426C>T p.F142= | Silent (SNP) | VAF 34/117 reads (29%) | catalogued as COSV101190332; called by muse, mutect2, varscan2
- EEF2K | c.870G>A p.E290= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as COSV99532808; called by muse, mutect2, varscan2
- FKBP15 | c.1965G>T p.L655= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV99438450; called by muse, mutect2, varscan2
- H4C11 | c.177G>A p.L59= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as rs371683547; called by muse, mutect2, varscan2
- HTR1E | c.1035G>A p.T345= | Silent (SNP) | VAF 43/127 reads (34%) | catalogued as rs199813634, COSV100541018; called by muse, mutect2, varscan2
- IAH1 | c.117G>A p.L39= | Silent (SNP) | VAF 25/66 reads (38%) | catalogued as COSV99432635; called by muse, mutect2, varscan2
- IGHG3 | c.553C>A p.R185= | Silent (SNP) | VAF 58/172 reads (34%) | called by muse, mutect2, varscan2
- ITIH2 | c.804G>A p.A268= | Silent (SNP) | VAF 46/80 reads (58%) | catalogued as rs752326969, COSV100623235; called by muse, mutect2, varscan2
- NAA30 | c.303C>G p.L101= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV100035813; called by muse, mutect2, varscan2
- NCS1 | c.534C>T p.S178= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV100969892; called by muse, mutect2, varscan2
- NME7 | c.729T>C p.I243= | Silent (SNP) | VAF 119/314 reads (38%) | catalogued as COSV100890957; called by muse, mutect2, varscan2
- OR10G8 | c.804T>C p.D268= | Silent (SNP) | VAF 66/163 reads (40%) | catalogued as COSV101461814; called by muse, mutect2, varscan2
- SLC6A17 | c.1092G>A p.E364= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as COSV100521174; called by muse, mutect2, varscan2
- SLCO5A1 | c.1731C>T p.Y577= | Silent (SNP) | VAF 54/134 reads (40%) | catalogued as COSV99479665; called by muse, mutect2, varscan2
- TECTA | c.4431C>T p.R1477= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as rs1243965610, COSV50689589; called by muse, mutect2, varscan2
- TMTC4 | c.2109C>T p.D703= (on ENST00000376234 / NM_001350577.2; = p.D722= on NM_032813.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 53/153 reads (35%) | catalogued as COSV100168569; called by muse, mutect2, varscan2
- XPO4 | c.1512A>G p.V504= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV99688280; called by muse, mutect2, varscan2
- ZNHIT2 | c.162C>T p.L54= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs539314451, COSV99658045; called by muse, varscan2
- AL353804.7 | chrX:73847996 C>T | 5'Flank (SNP) | VAF 33/42 reads (79%) | called by muse, mutect2, varscan2
- DDX41 | c.*303C>T | 3'UTR (SNP) | VAF 38/118 reads (32%) | catalogued as COSV100394274; called by muse, mutect2, varscan2
